Somatic mutation profile of tumor specimen TCGA-28-5204-01A (aliquot TCGA-28-5204-01A-01D-1486-08) from TCGA case TCGA-28-5204, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-28-5204-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2be04985-fe5b-4d9d-ac2b-57c9e96aa6be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5204-10A (Blood Derived Normal), aliquot TCGA-28-5204-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbffd96e-9ca7-4dea-be05-52fe81ada415

The open-access MAF lists 41 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Nonsense Mutation 3, Intron 2, RNA 1, Splice Region 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.3037A>T p.T1013S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.248); catalogued as COSV67017847; called by muse, mutect2, varscan2
- ADAM2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 99/134 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377755123, COSV55865150, COSV99698150; called by muse, mutect2, varscan2
- CARD16 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV65213193; called by muse, mutect2, varscan2
- CYLC2 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); catalogued as rs1334531194, COSV66338495; called by muse, mutect2, varscan2
- DACH1 | c.1975G>T p.E659* (on ENST00000619232 / NM_001366712.1; = p.E405* on NM_004392.6) | Nonsense Mutation (SNP) | VAF 90/233 reads (39%) | catalogued as COSV57509832; called by muse, mutect2, varscan2
- DBF4B | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs201641003, COSV59262069; called by muse, mutect2, varscan2
- DPEP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs368870164; called by muse, mutect2, varscan2
- FAM13C | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53252131; called by muse, mutect2, varscan2
- FPR2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs192933693, COSV60672310; called by muse, mutect2, varscan2
- GJC3 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs201992631, COSV57210618; called by muse, mutect2, varscan2
- GNAT3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775635099, COSV68069429; called by muse, mutect2, varscan2
- IRS4 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 211/236 reads (89%) | catalogued as COSV64534915; called by muse, mutect2, varscan2
- LDLR | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV52944633; called by muse, mutect2, varscan2
- MATN4 | c.1309G>A p.E437K (on ENST00000372754; = p.E396K on NM_003833.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | PolyPhen probably damaging (0.999); catalogued as rs755669114, COSV61350232; called by muse, mutect2, varscan2
- MUC17 | c.9686T>C p.V3229A | Missense Mutation (SNP) | VAF 35/1059 reads (3%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.857); catalogued as COSV60295674; called by muse, mutect2
- NEXMIF | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV50055662; called by muse, mutect2, varscan2
- OOEP | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 114/142 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs189355507, COSV64859382; called by muse, mutect2, varscan2
- OR51A2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs61744535, COSV66748350; called by muse, mutect2, varscan2
- PLCXD3 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 82/181 reads (45%) | catalogued as rs749287158, COSV60606708; called by muse, mutect2, varscan2
- RORB | c.128G>T p.G43V (on ENST00000396204 / NM_001365023.1; = p.G32V on NM_006914.4) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65338047, COSV65339450; called by muse, mutect2, varscan2
- RPL22L1 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV55557070; called by muse, mutect2, varscan2
- RTKN2 | c.1812G>C p.W604C | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59523230; called by muse, varscan2
- SLC35F3 | c.1006G>A p.V336I (on ENST00000366617 / NM_001300845.1; = p.V405I on NM_173508.4) | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs149597390; called by muse, mutect2, varscan2
- SLC38A1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV67064093; called by muse, mutect2, varscan2
- TMPRSS7 | c.1120A>G p.I374V (on ENST00000452346; = p.I248V on NM_001042575.2) | Missense Mutation (SNP) | VAF 279/690 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as rs757209497, COSV69981619; called by muse, mutect2, varscan2
- TNRC6C | c.3801C>T p.L1267= | Splice Region (SNP) | VAF 79/172 reads (46%) | catalogued as rs748706744, COSV56942991; called by muse, mutect2, varscan2
- TRPC4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs544186577, COSV58999065; called by muse, mutect2, varscan2
- TRRAP | c.11323C>T p.R3775W (on ENST00000359863 / NM_001244580.1; = p.R3746W on NM_003496.3) | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62815741, COSV62816369; called by muse, mutect2, varscan2
- UBE2M | c.411+1G>A p.X137_splice | Splice Site (SNP) | VAF 91/220 reads (41%) | catalogued as COSV53396419; called by muse, mutect2, varscan2
- YOD1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs1370721597, COSV60006637; called by muse, mutect2, varscan2
- ZNF235 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 156/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52157497; called by muse, mutect2, varscan2
- ZNF554 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs755248411, COSV57886353; called by muse, mutect2, varscan2
- GGA1 | c.417_425del p.K140_Q142del | In Frame Del (DEL) | VAF 44/192 reads (23%) | called by mutect2, pindel, varscan2
- NEFH | c.2849del p.A950Efs*106 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- ACAN | c.4971A>T p.P1657= | Silent (SNP) | VAF 150/356 reads (42%) | catalogued as COSV61364649; called by muse, mutect2, varscan2
- IL1A | c.813G>A p.A271= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs3783588; called by muse, mutect2, varscan2
- OR4C12 | c.318T>C p.G106= | Silent (SNP) | VAF 148/395 reads (37%) | catalogued as COSV58860543; called by muse, mutect2, varscan2
- TTN | c.60513C>T p.H20171= (on ENST00000591111; = p.H12747= on NM_003319.4) | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV60189771; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2792G>A | Intron (SNP) | VAF 81/227 reads (36%) | catalogued as COSV99805415; called by muse, varscan2
- ELAVL2 | c.-12-2824G>T | Intron (SNP) | VAF 96/267 reads (36%) | catalogued as COSV99805418, COSV99807114; called by muse, varscan2
- OR2W5 | n.673C>T | RNA (SNP) | VAF 61/179 reads (34%) | catalogued as rs201534844; called by muse, mutect2, varscan2
